CCDI case PBCDCC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/e0817152-f433-4b1c-bfcb-0828d378d7aa

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Choroid plexus papilloma, NOS: ICD-O-3 morphology code: 9390/0; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 1.9 years (707 days).

Biospecimens (3 samples)
- Sample 0DP6HK: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DP6HX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DP6IA: Tissue type: Tumor; Specimen type: Solid Tissue.
